Gene-level copy-number profile of tumor specimen TCGA-BF-A1Q0-01A from TCGA case TCGA-BF-A1Q0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 80.4 years (29,380 days).
Specimen TCGA-BF-A1Q0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.40715f44-b8b1-46fc-9595-1d30cce90476.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BF-A1Q0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 864 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9a55ea83-5db4-4dc1-b615-e4e1fbb7c767

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 783; copy number 3: 9,184; copy number 4: 13,589; copy number 5: 8,873; copy number 6: 9,719; copy number 7: 12,332; copy number 8: 2,704; copy number 9: 937; copy number 10: 1,212; copy number 11: 203; copy number 12: 196; copy number 13: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BF-A1Q0-01A-21D-A192-01): tumor purity 0.4, ploidy 5.61, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,575 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:200,027,614–200,177,420, 1 gene, copy number 9 (within-gene range 4–9): NR5A2.
- chr1:200,147,531–200,483,604, 8 genes, copy number 9: AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1.
- chr4:49,096–21,948,772, 412 genes, copy number 9–12 (within-gene range 7–12) (broad region; genes not listed).
- chr4:21,656,511–22,330,330, 5 genes, copy number 10 (within-gene range 8–10): AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P.
- chr4:27,207,505–32,745,525, 37 genes, copy number 9–10: AC024132.1, LINC02261, Y_RNA, AC024132.3, IGBP1P5, AC007106.2, AC007106.1, AC093791.2, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1.
- chr4:43,133,867–45,414,910, 25 genes, copy number 10 (within-gene range 7–10): AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1.
- chr6:1,507,322–2,525,976, 11 genes, copy number 9 (within-gene range 5–9): RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1.
- chr6:9,124,221–10,852,753, 28 genes, copy number 9 (within-gene range 6–9): AL137220.1, OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B.
- chr6:10,752,791–10,838,553, 2 genes, copy number 9 (within-gene range 6–9): RNA5SP203, MAK.
- chr6:29,993,209–32,859,851, 246 genes, copy number 9 (broad region; genes not listed).
- chr6:39,329,990–39,725,408, 1 gene, copy number 9 (within-gene range 5–9): KIF6.
- chr6:39,553,811–39,620,464, 2 genes, copy number 9: E2F4P1, RNU1-54P.
- chr6:49,714,325–50,181,007, 12 genes, copy number 9 (within-gene range 7–9): AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1.
- chr7:68,640,798–68,724,048, 2 genes, copy number 10: AC004910.1, RNA5SP231.
- chr7:79,543,911–80,391,474, 10 genes, copy number 9: NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P.
- chr7:80,377,554–80,377,835, 1 gene, copy number 9: SNRPBP1.
- chr7:81,431,731–83,162,930, 10 genes, copy number 9 (within-gene range 5–9): AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO.
- chr7:139,523,685–141,480,380, 33 genes, copy number 9–13 (within-gene range 5–13): CLEC2L, ERHP1, HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P, TMEM178B, AC006362.1.
- chr7:142,618,849–143,523,449, 74 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:56,050,038–98,942,827, 653 genes, copy number 10–11 (within-gene range 8–11) (broad region; genes not listed).
- chr8:111,093,263–145,066,685, 527 genes, copy number 10–11 (within-gene range 8–11) (broad region; genes not listed).
- chr12:28,133,249–28,581,511, 1 gene, copy number 9 (within-gene range 6–9): CCDC91.
- chr12:28,319,335–28,565,141, 3 genes, copy number 9: RNU4-54P, RNA5SP355, AC084754.1.
- chr12:68,686,951–69,959,097, 34 genes, copy number 9 (within-gene range 4–9): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:80,561,017–81,759,553, 16 genes, copy number 9 (within-gene range 6–9): AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr15:93,589,867–99,716,466, 109 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr17:31,518,432–39,451,272, 312 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
